Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6XQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6XQ-01B (Primary Tumor).

Specimen Date/Time:

IOD-0-3
Adenocarcinoma NOS
8/48/13
Site Esophagus, distal
thru C155
JW 8/8/2013

DIAGNOSIS

(A) ESOPHAGUS, DISTAL, BIOPSY:
INFILTRATING POORLY DIFFERENTIATED ADENOCARCINOMA.

GROSS DESCRIPTION

(A) DISTAL ESOPHAGUS BIOPSY - Two fragments of white-tan soft tissue, 0.3 x 0.3 x 0.2 cm each, entirely submitted in A.

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 5a3ba239-f4d0-4f31-ad5f-6775aeb9117f (TCGA-R6-A6XQ.D594830A-D5B8-4F83-9C3D-B8CF42B9B73E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).